Somatic mutation profile of tumor specimen TCGA-AB-2876-03A (aliquot TCGA-AB-2876-03A-01W-0732-08) from TCGA case TCGA-AB-2876, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.6 years (16,648 days).
Specimen TCGA-AB-2876-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8f0835b-f9dd-4ef9-8789-812e58beb095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2876-11A (Solid Tissue Normal), aliquot TCGA-AB-2876-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac6a41f1-be24-4168-aa7d-0995acc74377

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD18 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100728818; called by muse, mutect2
